TARGET case TARGET-20-PAWAIG — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a4bfefd-f31f-49ca-940b-1c4fa95884d6

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 17 years; Vital status: Dead; Days to death: 266 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.7 years (6,449 days); Year of diagnosis: 2013; Days to last follow up: 266 days; Sites of involvement: Central nervous system.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Treatment type: Stem Cell Transplantation, NOS; Timepoint category: First Complete Response.

Follow-up (2 entries)
- Days to follow up: 237 days; Days to first event: 237 days; First event: Relapse.
- Days to follow up: 266 days; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Positive.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Test: Positive.
- Trisomy 21: Positive.
- Trisomy 8: Negative.
- Day 0: Leukocytes 1.8 ×10³/µL; Blast Count 60%; Bone Marrow blast count 70%.
- Minimal Residual Disease (Flow Cytometry): Positive.

Biospecimens (1 sample)
- Sample TARGET-20-PAWAIG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AML1031_20230720.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 266
- WBC at Diagnosis: 1.8
- Bone marrow leukemic blast percentage (%): 70
- Peripheral blasts (%): 60
- CNS disease: Yes
- Chloroma: No
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: Yes
- MLL: Yes
- Minus Y: Yes
- Minus X: No
- Cytogenetic Code Other: MLL is NOT rearranged; however, MLL is amplified. There are four copies on the der(16), one on the Mar 1 in Clone 1, in addition to one on each of the normal #11 chromosomes. SCR-BH AGREED AT COG MEETING [4-14] THAT THE CASE IS NOT MLL REARRANGED, THUS …
- Cytogenetic Complexity: >6
- Primary Cytogenetic Code: MLL
- ISCN: 59,X,-Y,+4,-5,+8,+8,+10,+11,der(11)cryp del(11)(q23q23)inv(11)p15q23),+13,+13,+14,der(16)hsr(p13.3),+17,del(17)(p11.2p13),+19,+20,+21,+22,+mar1,+mar2[cp4].ish der(16)(MLL++++).ish mar1 (MLL+). ish der(11)(MLL-) This is one of three related clones, thi…
- FLT3/ITD positive?: No
- NPM mutation: No
- CEBPA mutation: No
- MRD at end of course 2: Yes
- CR status at end of course 1: not in CR
- CR status at end of course 2: CR
- Risk group: Standard Risk
- SCT in 1st CR: Yes
- Bone Marrow Site of Relapse/Induction Failure: Yes
- CNS Site of Relapse/Induction Failure: No
- Chloroma Site of Relapse/Induction Failure: No
- Cytogenetic Site of Relapse/Induction Failure: Yes
- Other Site of Relapse/Induction Failure: No
